CCDI case PBCVVE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/bae59169-09e7-4e80-acfa-f1d3e627f1cc

Demographics
Sex at birth: female.

Biospecimens (2 samples)
- Sample 0E18HU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E18I3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
